Somatic mutation profile of tumor specimen TARGET-20-PARYEB-09A (aliquot TARGET-20-PARYEB-09A-02D) from TARGET case TARGET-20-PARYEB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.1 years (6,986 days).
Specimen TARGET-20-PARYEB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 683f139d-2cee-4bd2-ac3b-f76d1497e474.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARYEB-14A (Bone Marrow Normal), aliquot TARGET-20-PARYEB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea9ace5d-f078-4c3c-8a05-88488279893d

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, Missense Mutation 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.818dup p.P274Tfs*8 | Frame Shift Ins (INS) | VAF 15/77 reads (19%) | catalogued as rs1559986946; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 108/229 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs28933386, CM013422, COSV61006575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 28/62 reads (45%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- WT1 | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as CM042136, COSV60066774, COSV60069640; called by muse, mutect2, varscan2
- GSE1 | c.1813_1814del p.L605Afs*8 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by pindel, varscan2
- EIF4A2 | c.1079+42C>T | Intron (SNP) | VAF 50/111 reads (45%) | catalogued as rs150834097; called by muse, mutect2, varscan2
